Somatic mutation profile of tumor specimen TCGA-CV-5430-01A (aliquot TCGA-CV-5430-01A-02D-1683-08) from TCGA case TCGA-CV-5430, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 61.8 years (22,577 days).
Specimen TCGA-CV-5430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ae972b9-3606-4f77-abee-913a4f4a8c79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5430-10A (Blood Derived Normal), aliquot TCGA-CV-5430-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30f2bb86-7503-4987-ad8c-55b3fbeb3133

The open-access MAF lists 151 somatic variants for this specimen: 107 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 39, Nonsense Mutation 7, Intron 4, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 2, Splice Region 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MC4R | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as rs1555691353, COSV100236154; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.3151G>T p.A1051S (on ENST00000372530 / NM_001198934.2; = p.A1023S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as COSV99768058; called by muse, mutect2, varscan2
- ACAN | c.1988C>A p.P663Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV61359394; called by muse, mutect2
- ACSM3 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99185053; called by muse, mutect2, varscan2
- ADCY4 | c.2633C>G p.S878* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100156468, COSV100156904; called by muse, mutect2
- AKAP9 | c.2776G>C p.E926Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100663244; called by muse, mutect2, varscan2
- AP2M1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99491013; called by muse, mutect2, varscan2
- APC | c.5077G>A p.E1693K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as CM942021, COSV99970610; called by muse, mutect2
- APC | c.6594G>C p.L2198F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.459); catalogued as COSV57334073, COSV99970614; called by muse, mutect2, varscan2
- APC | c.7116G>T p.Q2372H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); catalogued as rs1372802539, COSV99970619; called by muse, mutect2, varscan2
- APC | c.7288G>C p.D2430H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57366588, COSV99970621; called by muse, mutect2, varscan2
- ARID2 | c.4035C>A p.D1345E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.058); catalogued as COSV100537140; called by muse, mutect2, varscan2
- ASPM | c.7148G>C p.R2383T | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV99661214; called by muse, mutect2, varscan2
- BRAF | c.777C>G p.F259L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV56374905, COSV99970584; called by muse, mutect2
- BRCA2 | c.4711G>A p.E1571K | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV101204683; called by muse, mutect2, varscan2
- C10orf71 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1164993959, COSV100110708; called by muse, mutect2, varscan2
- C1orf189 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.471); catalogued as COSV100881044; called by muse, mutect2, varscan2
- CACNA1D | c.4996G>T p.E1666* (on ENST00000350061 / NM_001128840.3; = p.E1686* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV55436370, COSV99860310; called by muse, mutect2, varscan2
- CACNB2 | c.200G>A p.S67N (on ENST00000324631 / NM_201596.3; = p.S39N on NM_201571.4) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV99996691; called by muse, mutect2, varscan2
- CACYBP | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs1206197330, COSV100871647; called by muse, mutect2, varscan2
- CARMIL3 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV100549916; called by muse, mutect2
- CCDC170 | c.1898T>C p.M633T | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99498940; called by muse, mutect2, varscan2
- CD2BP2 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV99977263; called by muse, mutect2
- CD96 | c.554G>C p.S185T | Missense Mutation (SNP) | VAF 72/456 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.037); catalogued as COSV99343670; called by muse, mutect2, varscan2
- CHPF2 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as COSV50392272, COSV99223385; called by muse, mutect2, varscan2
- CNNM3 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs775166776, COSV100562602; called by muse, mutect2, varscan2
- CSGALNACT1 | c.849C>T p.F283= | Splice Region (SNP) | VAF 49/202 reads (24%) | catalogued as COSV100175717; called by muse, mutect2, varscan2
- DGKQ | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1240604518, COSV99893163; called by muse, mutect2
- DOCK2 | c.2090A>G p.E697G | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99915911; called by muse, mutect2
- EDRF1 | c.2171-1G>C p.X724_splice (on ENST00000356792 / NM_001202438.2; = p.X690_splice on NM_015608.2) | Splice Site (SNP) | VAF 32/140 reads (23%) | catalogued as COSV100523477, COSV100524081; called by muse, mutect2, varscan2
- FAT1 | c.9070G>T p.E3024* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV101499669; called by muse, mutect2, varscan2
- FCRL3 | c.844+1G>C p.X282_splice | Splice Site (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100943584; called by muse, mutect2, varscan2
- FOXO3 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100670255; called by muse, mutect2, varscan2
- FSIP1 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100618381; called by muse, mutect2, varscan2
- GABRB3 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769077258, COSV54660540; called by muse, mutect2, varscan2
- GAREM1 | c.2550C>G p.I850M (on ENST00000269209 / NM_001242409.2; = p.I849M on NM_022751.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52506022, COSV99331467; called by muse, mutect2, varscan2
- GRIA1 | c.1823G>A p.R608K | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99602685; called by muse, mutect2, varscan2
- GTF3C2 | c.5A>T p.D2V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99273339; called by muse, mutect2, varscan2
- H2BC5 | c.111C>G p.S37R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV56804062; called by muse, mutect2
- HASPIN | c.2343G>A p.M781I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99561633; called by muse, mutect2, varscan2
- HIVEP1 | c.2622C>G p.F874L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs775519055, COSV101045825; called by muse, mutect2, varscan2
- HR | c.3460C>T p.H1154Y | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100456059; called by muse, mutect2, varscan2
- HTR1E | c.1034C>A p.T345K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541353, COSV59507834; called by muse, mutect2, varscan2
- IL4I1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs750018786, COSV100352409; called by muse, mutect2, varscan2
- ITGA3 | c.536C>G p.T179S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1417040242, COSV99144357; called by muse, mutect2
- IZUMO1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55805965, COSV99711057; called by muse, mutect2, varscan2
- KCNV1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs1458883589, COSV52084840; called by muse, mutect2, varscan2
- LDLR | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52942625, COSV99370385; called by muse, mutect2
- LRRC8A | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); catalogued as rs1297439083, COSV99396975; called by muse, mutect2, varscan2
- LTBP1 | c.4366A>C p.T1456P (on ENST00000404816 / NM_206943.4; = p.T1130P on NM_000627.4) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); catalogued as COSV55378622, COSV99698933; called by muse, mutect2, varscan2
- LTN1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100798265; called by muse, mutect2, varscan2
- MACF1 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs777162400, COSV99242522; called by muse, mutect2, varscan2
- MINDY4 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377520823; called by muse, mutect2, varscan2
- MIS18BP1 | c.3039T>A p.D1013E | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.957); catalogued as COSV100173309; called by muse, mutect2, varscan2
- MPP3 | c.1275G>C p.K425N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV101263370, COSV68197472; called by muse, mutect2, varscan2
- MPZL1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100850418; called by muse, mutect2, varscan2
- NBR1 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100357654; called by muse, mutect2, varscan2
- NET1 | c.1736G>A p.R579Q (on ENST00000355029 / NM_001047160.3; = p.R525Q on NM_005863.5) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs757517284, COSV100742393; called by muse, mutect2, varscan2
- NFKBIZ | c.1472A>G p.N491S | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs187961189; called by muse, mutect2, varscan2
- NPHP3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs748204407, COSV100446899, COSV100447412; called by muse, mutect2, varscan2
- NUDT12 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as COSV50091214; called by muse, mutect2
- NUP210L | c.2105G>C p.G702A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99669259; called by muse, mutect2, varscan2
- OBSCN | c.14516C>A p.A4839E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99485043; called by muse, mutect2, varscan2
- OLA1 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99506912; called by muse, mutect2, varscan2
- PCDHB10 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99505121; called by muse, mutect2, varscan2
- PEX1 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99952440; called by muse, mutect2, varscan2
- PHKA2 | c.3448C>T p.L1150F | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV101177527; called by muse, mutect2, varscan2
- PKP4 | c.1265G>T p.S422I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1365742536, COSV101081681; called by muse, mutect2, varscan2
- PNLIP | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs142749694; called by muse, mutect2, varscan2
- PTK2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | catalogued as COSV100571307; called by muse, mutect2
- PTPN14 | c.3247C>G p.P1083A | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100872980; called by muse, mutect2
- PTPN4 | c.1939G>T p.A647S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99751569; called by muse, mutect2, varscan2
- RIC1 | c.2318A>G p.H773R | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); catalogued as COSV99318103; called by muse, varscan2
- RIC1 | c.2344C>A p.L782M | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1001186704, COSV99318107; called by muse, varscan2
- RIPK1 | c.1182G>C p.Q394H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.45); catalogued as COSV99454989; called by muse, mutect2, varscan2
- ROS1 | c.3560T>C p.V1187A | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100877768; called by muse, mutect2, varscan2
- SEMA3A | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99548154; called by muse, mutect2, varscan2
- SGCE | c.359C>T p.P120L (on ENST00000647096; = p.P84L on NM_003919.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV99722978; called by muse, mutect2, varscan2
- SIPA1L1 | c.3602C>T p.T1201M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs753081355, COSV62169577; called by muse, mutect2, varscan2
- SLC43A1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99561262; called by muse, mutect2, varscan2
- SP3 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1266612387, COSV100022263; called by muse, mutect2, varscan2
- STRBP | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100724378; called by muse, mutect2, varscan2
- TAF8 | c.639G>A p.L213= | Splice Region (SNP) | VAF 64/513 reads (12%) | catalogued as COSV100881212; called by muse, mutect2, varscan2
- TENM1 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 176/276 reads (64%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.622); catalogued as COSV100951156; called by muse, mutect2, varscan2
- TMEM64 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 115/174 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101376096; called by muse, mutect2, varscan2
- TNFAIP6 | c.581A>C p.E194A | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99694121; called by muse, mutect2, varscan2
- TNFSF8 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV99802149; called by muse, mutect2, varscan2
- TTC30A | c.797A>T p.N266I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100826242; called by muse, mutect2, varscan2
- TTN | c.59585G>A p.G19862E (on ENST00000591111; = p.G12438E on NM_003319.4) | Missense Mutation (SNP) | VAF 33/242 reads (14%) | PolyPhen probably damaging (0.955); catalogued as rs768027450, COSV100633040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.12478G>A p.A4160T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV100243372; called by muse, mutect2, varscan2
- VWA5A | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100795764; called by muse, mutect2, varscan2
- WWC1 | c.2878C>T p.R960* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs1016369196, COSV54650280; called by muse, mutect2, varscan2
- ZFHX4 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99268476; called by muse, mutect2, varscan2
- ZNF155 | c.1446dup p.P483Tfs*5 | Frame Shift Ins (INS) | VAF 16/104 reads (15%) | catalogued as rs539072881; called by pindel, varscan2
- ZNF208 | c.525T>G p.C175W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237246; called by muse, mutect2, varscan2
- ZNF462 | c.2288G>C p.R763T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV52929039; called by muse, mutect2, varscan2
- ZNF598 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV101461991, COSV70910088; called by muse, mutect2, varscan2
- ZZEF1 | c.5075A>G p.N1692S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1048744025, COSV101068156; called by muse, mutect2, varscan2
- AREG | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CASP2 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); called by muse, mutect2
- DONSON | c.1634C>G p.P545R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- EPB41L4B | c.2465del p.F822Sfs*26 | Frame Shift Del (DEL) | VAF 53/115 reads (46%) | called by mutect2, pindel, varscan2
- FBXO30 | c.834dup p.D279* | Frame Shift Ins (INS) | VAF 33/138 reads (24%) | called by mutect2, pindel, varscan2
- FCGBP | c.8386G>C p.E2796Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- FHL2 | c.786dup p.F263Lfs*28 | Frame Shift Ins (INS) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- TP53 | c.267_277del p.S90Vfs*55 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- VPS13B | c.3539del p.G1180Vfs*6 | Frame Shift Del (DEL) | VAF 73/406 reads (18%) | called by mutect2, pindel, varscan2
- ADAM17 | c.720C>T p.G240= | Silent (SNP) | VAF 74/198 reads (37%) | catalogued as COSV100176603; called by muse, mutect2, varscan2
- ALPK2 | c.5913C>A p.I1971= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs61732436, COSV100864886, COSV64494241; called by muse, mutect2, varscan2
- ATP2C1 | c.2187C>G p.L729= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV100147034; called by muse, mutect2, varscan2
- CDH4 | c.2592C>T p.S864= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100849765; called by muse, mutect2, varscan2
- CREB3L3 | c.972C>T p.V324= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs768895841, COSV50246113; called by muse, mutect2, varscan2
- DNAH2 | c.3141C>G p.L1047= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV101209477, COSV101209636, COSV66718044; called by muse, mutect2, varscan2
- ENTPD6 | c.897G>A p.L299= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100737196; called by muse, mutect2, varscan2
- EPHA7 | c.741G>A p.R247= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV65170705; called by muse, mutect2, varscan2
- ESPL1 | c.1122G>A p.L374= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV99229856; called by muse, mutect2, varscan2
- EWSR1 | c.1602C>T p.F534= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as rs138837921; called by muse, mutect2, varscan2
- FOXE3 | c.303C>T p.I101= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs750716260, COSV100624060; called by muse, mutect2
- FZD1 | c.1386C>T p.I462= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs150597135, COSV99842806; called by muse, mutect2, varscan2
- HDHD3 | c.361C>T p.L121= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV99445242; called by muse, mutect2, varscan2
- HNF1A | c.468G>A p.T156= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99983081; called by muse, mutect2, varscan2
- HOXC4 | c.561C>A p.I187= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs767966253, COSV100324428, COSV57698584; called by muse, mutect2, varscan2
- IZUMO4 | c.33G>T p.T11= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100642754, COSV100643115, COSV61433378; called by muse, mutect2, varscan2
- KY | c.1266C>T p.S422= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs376295684; called by muse, mutect2, varscan2
- M6PR | c.654A>G p.K218= | Silent (SNP) | VAF 52/350 reads (15%) | catalogued as COSV99134337; called by muse, mutect2, varscan2
- MAGEA11 | c.912T>C p.C304= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV100290741; called by muse, mutect2, varscan2
- MYH3 | c.1956C>T p.F652= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99879006; called by muse, mutect2, varscan2
- NLRP1 | c.315G>A p.L105= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99335658; called by muse, mutect2
- OR1E1 | c.348G>A p.V116= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100492055; called by muse, mutect2, varscan2
- PAPPA2 | c.2865G>T p.L955= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as COSV100868764; called by muse, mutect2, varscan2
- PDE12 | c.63G>A p.L21= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100239993; called by mutect2, varscan2
- PEAR1 | c.2970C>T p.D990= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs1267456992, COSV99442519; called by muse, mutect2, varscan2
- PF4 | c.228G>A p.L76= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV99933134; called by muse, mutect2
- PKD1L1 | c.5304C>A p.V1768= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99221583; called by muse, mutect2, varscan2
- PPL | c.3753C>G p.L1251= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99278128, COSV99278732; called by muse, mutect2, varscan2
- PRR35 | c.1590C>G p.L530= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99216608; called by muse, mutect2, varscan2
- PRRC2C | c.3009A>G p.R1003= (on ENST00000367742; = p.R1001= on NM_015172.4) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100146197; called by muse, mutect2, varscan2
- PSME4 | c.1320A>G p.T440= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101122710; called by muse, mutect2
- QSOX1 | c.1593C>G p.L531= | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as rs768556738, COSV100852969, COSV62580518; called by muse, mutect2, varscan2
- SLC17A6 | c.99G>A p.K33= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99582501; called by muse, mutect2, varscan2
- SLC2A9 | c.1581C>T p.I527= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as rs779863644, COSV53317776; called by muse, mutect2, varscan2
- TAF7L | c.180C>T p.D60= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV63300051; called by muse, mutect2
- TBC1D10A | c.174C>T p.F58= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1000873586, COSV99305002; called by muse, mutect2, varscan2
- WDR47 | c.528C>A p.I176= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV100728474; called by muse, mutect2, varscan2
- ZNF616 | c.570T>C p.C190= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as COSV57510650; called by muse, mutect2, varscan2
- ZNF675 | c.780A>G p.E260= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100705217; called by muse, mutect2, varscan2
- CALCR | c.52-3331G>C | Intron (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100810906; called by muse, mutect2
- KIR3DX1 | n.430C>A | RNA (SNP) | VAF 34/66 reads (52%) | catalogued as COSV99683721; called by muse, mutect2, varscan2
- SPG7 | c.1303+4205C>G | Intron (SNP) | VAF 37/198 reads (19%) | catalogued as COSV99245492; called by muse, mutect2, varscan2
- TMBIM6 | c.-31+550G>C | Intron (SNP) | VAF 13/18 reads (72%) | catalogued as COSV57278519, COSV99920664; called by muse, mutect2, varscan2
- WNK1 | c.2140-2759_2140-2758del | Intron (DEL) | VAF 6/58 reads (10%) | called by pindel, varscan2
